Gene-level copy-number profile of tumor specimen SM-JU33T from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33T: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cca9f2a5-def0-4d13-916f-c08b5416071d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105210 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/5f8f3bbb-1a88-44c6-9dd0-51a6614821dd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 2; copy number 2: 3,796; copy number 3: 61; copy number 4: 49,674; copy number 5: 153; copy number 6: 1,633; copy number 7: 9; copy number 8: 28; copy number 9: 1; copy number 10: 2,716; copy number 17: 2; copy number 30: 13; copy number 32: 10; copy number 34: 3; copy number 37: 21; copy number 40: 16; copy number 43: 27; copy number 44: 16; copy number 45: 3; copy number 56: 22; copy number 63: 1; copy number 88: 1; copy number 107: 25; copy number 116: 30; copy number 132: 10; copy number 142: 51.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,562,149, 10 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24.
- chr9:20,341,669–23,438,700, 69 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,968 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,795,623–206,464,443, 85 genes, copy number 30–44 (broad region; genes not listed).
- chr1:230,002,372–231,040,254, 24 genes, copy number 37–45: LINC01736, GALNT2, AL136988.2, AL136988.1, PGBD5, LINC01737, AL158214.1, COG2, AL158214.2, AGT, AL512328.1, CAPN9, RNA5SP79, AL118511.2, C1orf198, AL118511.1, AL118511.4, AL118511.3, RN7SL837P, TTC13, ARV1, FAM89A, MIR1182, AL732414.1.
- chr7:37,032–53,366,209, 883 genes, copy number 10 (broad region; genes not listed).
- chr7:54,542,325–144,836,395, 1,784 genes, copy number 9–142 (broad region; genes not listed).
- chr7:149,262,171–156,973,176, 167 genes, copy number 10 (broad region; genes not listed).
- chr7:157,466,231–159,233,377, 25 genes, copy number 10: AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
